Somatic mutation profile of tumor specimen TCGA-24-1849-01A (aliquot TCGA-24-1849-01A-01W-0639-09) from TCGA case TCGA-24-1849, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 80.9 years (29,555 days).
Specimen TCGA-24-1849-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6f839ed-bb4b-4154-8c47-8b7fb8516f5f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1849-10A (Blood Derived Normal), aliquot TCGA-24-1849-10A-01W-0639-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2dc0256e-004d-4780-ab82-087efbbbe79e

The open-access MAF lists 124 somatic variants for this specimen: 97 protein-altering or splice-affecting, 25 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 25, Splice Site 4, Frame Shift Del 4, Nonsense Mutation 2, Splice Region 1, Nonstop Mutation 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYSF | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 59/244 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149827237, CM053209; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1575del p.F526Lfs*6 | Frame Shift Del (DEL) | VAF 74/171 reads (43%) | catalogued as rs1131690876, CM030507; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.97-1G>A p.X33_splice | Splice Site (SNP) | VAF 132/414 reads (32%) | hotspot (GDC flag); catalogued as CS971912, COSV52665806, COSV52762622, COSV52838014; called by muse, mutect2, varscan2
- ADAM18 | c.1056T>A p.S352R | Missense Mutation (SNP) | VAF 55/209 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.071); catalogued as COSV55846813; called by muse, mutect2, varscan2
- ADGRL3 | c.1342A>T p.N448Y (on ENST00000506720 / NM_001322402.2; = p.N380Y on NM_015236.6) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72268173; called by muse, mutect2, varscan2
- AFAP1L1 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 11/273 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99695832; called by muse, mutect2
- ANKRD12 | c.2835A>T p.K945N | Missense Mutation (SNP) | VAF 67/277 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.439); catalogued as COSV50823971; called by muse, mutect2, varscan2
- ATG4D | c.990C>G p.C330W | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57264400; called by muse, mutect2, varscan2
- ATP5F1A | c.645G>C p.Q215H | Missense Mutation (SNP) | VAF 17/322 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99958878; called by muse, mutect2
- ATP5F1C | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs755781927, COSV59621499; called by muse, mutect2, varscan2
- BRDT | c.1119T>G p.F373L | Missense Mutation (SNP) | VAF 47/239 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs373509947; called by muse, mutect2, varscan2
- BTK | c.491G>C p.G164A | Missense Mutation (SNP) | VAF 40/380 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CX163523, COSV58119602; called by muse, mutect2
- BTNL9 | c.669C>A p.S223R | Missense Mutation (SNP) | VAF 40/376 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV59795603, COSV59798926; called by muse, mutect2
- C15orf39 | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.561); catalogued as rs769306778, COSV100641380, COSV62296495; called by muse, varscan2
- C15orf39 | c.1314G>C p.E438D | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV62296504; called by muse, mutect2, varscan2
- CARD14 | c.991C>A p.L331M | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.758); catalogued as COSV60123168; called by muse, mutect2, varscan2
- CATSPER1 | c.298C>A p.P100T | Missense Mutation (SNP) | VAF 95/350 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); catalogued as COSV56410397; called by muse, mutect2, varscan2
- CATSPERE | c.212G>T p.C71F | Missense Mutation (SNP) | VAF 59/255 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63677633; called by muse, mutect2, varscan2
- CHRM3 | c.564G>C p.M188I | Missense Mutation (SNP) | VAF 58/228 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55087950, COSV99699512; called by muse, mutect2, varscan2
- CLCN1 | c.1222C>G p.P408A | Missense Mutation (SNP) | VAF 118/443 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs202019723, CM076097; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLK3 | c.906G>T p.E302D (on ENST00000395066 / NM_001130028.1; = p.E154D on NM_003992.4) | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100775873; called by muse, mutect2
- CLTCL1 | c.3625G>A p.G1209R | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.371); catalogued as rs1555939434, COSV99594898; called by muse, mutect2, varscan2
- COX18 | c.625A>G p.T209A | Missense Mutation (SNP) | VAF 38/199 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.033); catalogued as rs749730324, COSV55720389; called by muse, mutect2, varscan2
- CRMP1 | c.724A>C p.I242L | Missense Mutation (SNP) | VAF 171/533 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as COSV61479915; called by muse, mutect2, varscan2
- CTH | c.971A>G p.H324R | Missense Mutation (SNP) | VAF 57/258 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.143); catalogued as COSV61008203; called by muse, mutect2, varscan2
- CXorf38 | c.836T>C p.L279P | Missense Mutation (SNP) | VAF 20/553 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100010321; called by muse, mutect2
- CYP7B1 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 64/274 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as COSV59587400; called by muse, mutect2, varscan2
- DAB2IP | c.1597C>G p.P533A (on ENST00000408936; = p.P505A on NM_032552.3) | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52258488; called by muse, mutect2, varscan2
- DCAF1 | c.2144C>T p.P715L | Missense Mutation (SNP) | VAF 35/792 reads (4%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs782134454, COSV100244353; called by muse, mutect2
- DSN1 | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.812); catalogued as COSV101041014; called by muse, mutect2
- ENPP1 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 51/208 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1370913047, COSV62934810; called by muse, mutect2, varscan2
- ERGIC1 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 44/184 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs775711743, COSV58595702; called by muse, mutect2, varscan2
- EXOC3 | c.2053T>C p.Y685H | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.35); catalogued as COSV100155283; called by muse, mutect2
- EXOC7 | c.2030A>T p.D677V (on ENST00000335146 / NM_001145297.4; = p.D595V on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58035977; called by muse, mutect2, varscan2
- FCRL5 | c.2758G>C p.E920Q | Missense Mutation (SNP) | VAF 52/243 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.226); catalogued as COSV62513972; called by muse, mutect2, varscan2
- GCC1 | c.1838C>G p.S613C | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV58461998, COSV58462430; called by muse, mutect2, varscan2
- GFPT2 | c.44C>T p.T15M | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1010915951, COSV53807947; called by muse, mutect2
- GGT7 | c.382C>G p.Q128E | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV100321892; called by muse, mutect2, varscan2
- GPC5 | c.1182C>G p.Y394* | Nonsense Mutation (SNP) | VAF 234/427 reads (55%) | catalogued as COSV65595261; called by muse, varscan2
- GRIA2 | c.2261G>A p.G754D | Missense Mutation (SNP) | VAF 19/201 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52406810; called by muse, mutect2
- HCK | c.1499A>T p.E500V | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV52942203; called by muse, mutect2, varscan2
- HIPK1 | c.2564+2T>G p.X855_splice | Splice Site (SNP) | VAF 12/252 reads (5%) | catalogued as COSV100478861; called by muse, mutect2
- HLCS | c.622G>C p.D208H | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.116); catalogued as COSV60793088; called by muse, mutect2, varscan2
- HMMR | c.545G>A p.R182K | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100700987; called by muse, mutect2
- IGLV4-60 | c.147C>G p.H49Q | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.33); catalogued as COSV66503521; called by muse, mutect2, varscan2
- KAT6A | c.4421G>T p.C1474F | Missense Mutation (SNP) | VAF 32/676 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99704898; called by muse, mutect2
- KCNH7 | c.1439A>G p.E480G | Missense Mutation (SNP) | VAF 30/242 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs1440659911, COSV59795161; called by muse, mutect2, varscan2
- KCNH8 | c.558G>C p.L186F | Missense Mutation (SNP) | VAF 51/249 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.753); catalogued as COSV60462534; called by muse, mutect2, varscan2
- LLGL1 | c.1448G>T p.C483F | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100375295; called by muse, mutect2
- LRRC59 | c.849C>G p.I283M | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV56814376; called by muse, mutect2, varscan2
- MAMDC2 | c.1520G>C p.G507A | Missense Mutation (SNP) | VAF 33/257 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.799); catalogued as COSV65852366; called by muse, mutect2, varscan2
- MAN2A1 | c.1652C>T p.S551L | Missense Mutation (SNP) | VAF 33/227 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as COSV54851088; called by muse, mutect2, varscan2
- MAP3K19 | c.226A>T p.R76W | Missense Mutation (SNP) | VAF 35/473 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100208440; called by muse, mutect2
- MINAR1 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 71/328 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59581669; called by muse, mutect2, varscan2
- MSH4 | c.1129C>G p.Q377E | Missense Mutation (SNP) | VAF 86/395 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV54202018, COSV99590584; called by muse, mutect2, varscan2
- MTF2 | c.818G>C p.C273S | Missense Mutation (SNP) | VAF 75/245 reads (31%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as COSV64770357; called by muse, mutect2, varscan2
- MYH3 | c.4756C>A p.Q1586K | Missense Mutation (SNP) | VAF 25/577 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.155); catalogued as COSV99878097; called by muse, mutect2
- NCEH1 | c.53C>G p.P18R | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV56434353; called by muse, mutect2, varscan2
- NETO1 | c.1051T>G p.C351G | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55005828; called by muse, mutect2, varscan2
- NUP54 | c.401G>C p.R134T | Missense Mutation (SNP) | VAF 46/278 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99345248; called by muse, mutect2
- OGDH | c.2088C>G p.D696E | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); catalogued as COSV99758686; called by muse, mutect2
- OR4D1 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 185/364 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.17); catalogued as COSV52124970; called by muse, mutect2, varscan2
- ORC1 | c.1083G>A p.R361= | Splice Region (SNP) | VAF 23/338 reads (7%) | catalogued as COSV100856650; called by muse, mutect2
- PADI3 | c.1952G>T p.C651F | Missense Mutation (SNP) | VAF 5/130 reads (4%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100968462; called by muse, mutect2
- PARP9 | c.1749G>T p.E583D | Missense Mutation (SNP) | VAF 19/645 reads (3%) | SIFT tolerated (0.51); PolyPhen benign (0.014); catalogued as COSV100831086; called by muse, mutect2
- PCDHB10 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 74/261 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV53378225; called by muse, mutect2, varscan2
- PCNX2 | c.6035G>A p.R2012Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs747342134, COSV50797516; called by muse, varscan2
- PIGO | c.1165C>T p.Q389* | Nonsense Mutation (SNP) | VAF 61/280 reads (22%) | catalogued as COSV53053528; called by muse, mutect2, varscan2
- PKHD1L1 | c.7039G>C p.A2347P | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.304); catalogued as COSV65742123; called by muse, mutect2, varscan2
- PLCL1 | c.1037C>T p.T346I | Missense Mutation (SNP) | VAF 149/436 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.101); catalogued as rs373797233; called by muse, mutect2, varscan2
- PLEKHB2 | c.591C>G p.N197K (on ENST00000409279; = p.N196K on NM_017958.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 91/361 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as COSV52174550, COSV52175697; called by muse, mutect2, varscan2
- POLG | c.1552G>A p.A518T | Missense Mutation (SNP) | VAF 46/754 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.078); catalogued as COSV99174693; called by muse, mutect2
- PTGS1 | c.1087G>C p.E363Q | Missense Mutation (SNP) | VAF 98/377 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.298); catalogued as COSV56291529, COSV56292135; called by muse, mutect2, varscan2
- PTPRN2 | c.1850C>T p.A617V | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753849491, COSV67030982, COSV67035376; called by muse, mutect2, varscan2
- RAG2 | c.1225G>T p.D409Y | Missense Mutation (SNP) | VAF 30/345 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100271234; called by muse, mutect2
- SCFD2 | c.569C>A p.A190D | Missense Mutation (SNP) | VAF 9/305 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.198); catalogued as COSV101189341; called by muse, mutect2
- SEMA4B | c.479A>C p.Y160S | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV60173348; called by muse, mutect2, varscan2
- SH3BP4 | c.1976G>T p.G659V | Missense Mutation (SNP) | VAF 14/207 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100749114; called by muse, mutect2
- SIX4 | c.696G>C p.E232D | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as COSV53669411; called by muse, mutect2, varscan2
- SPRED3 | c.282G>C p.Q94H | Missense Mutation (SNP) | VAF 30/442 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100612651; called by muse, mutect2
- STEAP1 | c.122C>A p.P41H | Missense Mutation (SNP) | VAF 110/385 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV51881522; called by muse, mutect2, varscan2
- STIL | c.259G>C p.D87H | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99680847; called by muse, mutect2
- TAS1R2 | c.1972G>A p.A658T | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs145202761; called by muse, varscan2
- TDRD3 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 281/663 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV52156264; called by muse, mutect2, varscan2
- TMEM201 | c.429+1G>T p.X143_splice | Splice Site (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100440376; called by muse, mutect2
- TMEM87B | c.242G>T p.C81F | Missense Mutation (SNP) | VAF 27/568 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs199661294, COSV99314231; called by muse, mutect2
- TTI1 | c.3188A>G p.H1063R | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV100989625; called by muse, mutect2
- USP36 | c.809A>G p.D270G | Missense Mutation (SNP) | VAF 55/122 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1446163420, COSV61751497; called by muse, mutect2, varscan2
- VILL | c.115C>T p.H39Y | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV99378726; called by muse, mutect2
- WDR76 | c.1843G>A p.G615R | Missense Mutation (SNP) | VAF 15/233 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1020192578; called by muse, mutect2
- ZSWIM8 | c.1020G>T p.R340S | Missense Mutation (SNP) | VAF 4/94 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101289869; called by muse, mutect2
- ATP13A4 | c.547G>T p.G183W | Missense Mutation (SNP) | VAF 24/654 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CRYBB1 | c.299+2_299+17del p.X100_splice | Splice Site (DEL) | VAF 95/330 reads (29%) | called by mutect2, pindel, varscan2
- DDR1 | c.468del p.M159Wfs*16 | Frame Shift Del (DEL) | VAF 24/149 reads (16%) | called by mutect2, pindel, varscan2
- GLB1L3 | c.1952_*3del | Nonstop Mutation (DEL) | VAF 12/92 reads (13%) | called by mutect2, pindel
- L1TD1 | c.306del p.Q103Sfs*3 | Frame Shift Del (DEL) | VAF 34/166 reads (20%) | called by mutect2, pindel, varscan2
- ST3GAL5 | c.992_1002del p.P331Lfs*16 (on ENST00000377332; = p.P371Lfs*16 on NM_003896.4) | Frame Shift Del (DEL) | VAF 75/597 reads (13%) | called by mutect2, pindel, varscan2
- ALOX15B | c.1206G>A p.L402= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs1181403775, COSV66479391; called by muse, mutect2, varscan2
- CDKL5 | c.1761A>G p.A587= | Silent (SNP) | VAF 56/623 reads (9%) | catalogued as COSV101184274; called by muse, mutect2
- CELSR2 | c.7725G>T p.T2575= | Silent (SNP) | VAF 10/128 reads (8%) | catalogued as rs761491369, COSV99603645, COSV99604185; called by muse, mutect2
- COBLL1 | c.1206A>G p.A402= (on ENST00000392717; = p.A364= on NM_014900.5) | Silent (SNP) | VAF 18/395 reads (5%) | catalogued as COSV99527756; called by muse, mutect2
- DCAF1 | c.2322C>T p.I774= | Silent (SNP) | VAF 56/335 reads (17%) | catalogued as rs781835730, COSV60042580; called by muse, mutect2, varscan2
- DENND5A | c.660G>T p.R220= | Silent (SNP) | VAF 12/226 reads (5%) | catalogued as COSV100064494, COSV60231857; called by muse, mutect2
- DNASE1L3 | c.648G>A p.L216= | Silent (SNP) | VAF 81/224 reads (36%) | catalogued as rs1165284259, COSV59155816; called by muse, mutect2, varscan2
- ESPL1 | c.2715G>A p.L905= | Silent (SNP) | VAF 70/434 reads (16%) | catalogued as COSV57759153; called by muse, mutect2, varscan2
- FBN2 | c.2223C>T p.C741= | Silent (SNP) | VAF 11/282 reads (4%) | catalogued as COSV99326805; called by muse, mutect2
- GPR31 | c.435C>T p.L145= | Silent (SNP) | VAF 45/121 reads (37%) | catalogued as COSV64761385; called by muse, mutect2, varscan2
- GPX6 | c.621C>T p.V207= | Silent (SNP) | VAF 26/154 reads (17%) | catalogued as COSV62657416; called by muse, mutect2, varscan2
- IFNK | c.396C>T p.D132= | Silent (SNP) | VAF 36/440 reads (8%) | catalogued as rs746514030, COSV51783799; called by muse, mutect2
- MARCHF10 | c.318G>A p.Q106= | Silent (SNP) | VAF 225/1073 reads (21%) | catalogued as COSV60886810; called by muse, mutect2, varscan2
- OR10G9 | c.135G>A p.L45= | Silent (SNP) | VAF 154/738 reads (21%) | catalogued as COSV66686182; called by muse, mutect2, varscan2
- PDE6B | c.1764C>T p.F588= | Silent (SNP) | VAF 33/111 reads (30%) | catalogued as rs776654182, COSV99727361; called by muse, varscan2
- POP1 | c.2511G>A p.Q837= | Silent (SNP) | VAF 31/512 reads (6%) | catalogued as COSV100855767; called by muse, mutect2
- SATB1 | c.2082G>A p.Q694= | Silent (SNP) | VAF 64/568 reads (11%) | catalogued as COSV100113084, COSV58669124; called by muse, mutect2
- SGO2 | c.234A>G p.E78= | Silent (SNP) | VAF 114/372 reads (31%) | catalogued as COSV63415125; called by muse, mutect2, varscan2
- TAS2R42 | c.882A>G p.T294= | Silent (SNP) | VAF 30/184 reads (16%) | catalogued as COSV100516848; called by muse, mutect2, varscan2
- TLR4 | c.1728T>C p.L576= (on ENST00000355622 / NM_138554.5; = p.L536= on NM_003266.4) | Silent (SNP) | VAF 21/252 reads (8%) | catalogued as rs1053396077, COSV62924694; called by muse, mutect2
- TMEM132E | c.2361C>T p.F787= (on ENST00000321639; = p.F877= on NM_001304438.2) | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV58696596; called by muse, mutect2, varscan2
- TTLL12 | c.1164C>T p.P388= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV53355020; called by muse, mutect2, varscan2
- VPS13B | c.7671A>G p.L2557= | Silent (SNP) | VAF 61/200 reads (31%) | catalogued as rs1388026353, COSV62140156; called by muse, mutect2, varscan2
- WDR31 | c.681T>G p.P227= (on ENST00000374193 / NM_001006615.3; = p.P226= on NM_145241.5) | Silent (SNP) | VAF 50/249 reads (20%) | catalogued as COSV59146015; called by muse, mutect2, varscan2
- ZNF701 | c.1221T>C p.L407= (on ENST00000301093; = p.L341= on NM_018260.3) | Silent (SNP) | VAF 94/704 reads (13%) | catalogued as COSV56524389; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851018 G>T | 3'Flank (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2
- SNORD115-21 | n.71C>T | RNA (SNP) | VAF 34/128 reads (27%) | catalogued as rs574273914; called by muse, mutect2, varscan2
